Gene-level copy-number profile of tumor specimen MP2PRT-PASZNV-TTP1-A from MP2PRT case MP2PRT-PASZNV, project MP2PRT-WT (Molecular Profiling to Predict Response to Treatment - Wilms Tumor). Sex at birth: female; Vital status: Dead; Primary diagnosis: Nephroblastoma, NOS; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 5.3 years (1,919 days).
Specimen MP2PRT-PASZNV-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 66195a99-d5d6-4e56-8c22-bb49321c0518.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator MP2PRT-PASZNV-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,224 have no estimate.
https://portal.gdc.cancer.gov/files/591752fe-985a-4776-9db3-be4f3e2a65ff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 6,721; copy number 2: 50,279; copy number 3: 357; copy number 4: 107; copy number 5: 573; copy number 6: 144; copy number 7: 114; copy number 8: 92.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr11:90,031,106–90,087,131, 7 genes: TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1.
- chr22:18,715,815–18,757,906, 2 genes: PPP1R26P4, FAM230E.
- chr22:38,952,741–38,992,804, 2 genes (within-gene range 0–1): APOBEC3A, APOBEC3B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 923 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:146,288,596–148,796,325, 85 genes, copy number 7 (broad region; genes not listed).
- chr1:149,606,334–154,351,304, 278 genes, copy number 5–8 (broad region; genes not listed).
- chr1:154,502,219–171,251,857, 531 genes, copy number 5–6 (within-gene range 2–6) (broad region; genes not listed).
- chr1:173,931,084–175,335,459, 26 genes, copy number 7 (within-gene range 3–7): RC3H1, RNA5SP68, RC3H1-IT1, LINC02776, RPL30P1, RABGAP1L-DT, RABGAP1L, AL022400.1, GPR52, BANF1P4, NDUFAF4P4, Z99127.2, RABGAP1L-IT1, Z99127.1, RABGAP1L-AS1, RNU6-307P, Z99127.3, CACYBP, MRPS14, Y_RNA, ENTR1P2, TNN, KIAA0040, AL008626.1, RPS29P4, Z94057.1.
- chr1:184,387,029–184,629,019, 1 gene, copy number 7 (within-gene range 3–7): C1orf21.
- chr1:184,566,511–184,672,166, 2 genes, copy number 7: AL078645.2, AL713852.1.

Autosomal genes at a single copy (total copy number 1): 6,714. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
